TCGA case TCGA-CJ-6028 — Kidney Renal Clear Cell Carcinoma (TCGA-KIRC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Kidney; Tissue source site: MD Anderson Cancer Center. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/2890b330-8ba5-4031-bed5-13e9d1d75af9

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 58 years; Vital status: Dead; Days to death: 1,625 days (4.4 years).

Diagnoses (2)
1. Clear cell adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8310/3; ICD-10 code: C64.9; Tissue or organ of origin: Kidney, NOS; Site of resection or biopsy: Kidney, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 58.5 years (21,380 days); Year of diagnosis: 2003; AJCC staging edition: 7th; AJCC pathologic T: T3a; AJCC pathologic N: NX; AJCC pathologic M: M1; AJCC pathologic stage: Stage IV; Tumor grade: G4; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Immunotherapy (Including Vaccines); Therapeutic agents: Vitespen; Initial disease status: Progressive Disease; Days to treatment start: 41 days; Days to treatment end: 130 days; Treatment dose: 4 mL; Prescribed dose: 0.4; Prescribed dose units: mL; Route of administration: Subcutaneous.
   Treatment given: Treatment type: Radiation, Stereotactic/Gamma Knife/SRS; Initial disease status: Progressive Disease; Days to treatment start: 165 days; Days to treatment end: 165 days; Treatment dose: 3,600 cGy; Number of fractions: 2; Treatment anatomic sites: Distant Site.
   Treatment given: Treatment type: Immunotherapy (Including Vaccines); Therapeutic agents: Interferon; Initial disease status: Progressive Disease; Days to treatment start: 336 days; Days to treatment end: 392 days (1.1 years); Route of administration: Subcutaneous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Capecitabine; Initial disease status: Progressive Disease; Days to treatment start: 392 days (1.1 years); Days to treatment end: 903 days (2.5 years); Number of cycles: 2; Prescribed dose: 1500; Prescribed dose units: mg/m2/day; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Gemcitabine; Initial disease status: Progressive Disease; Days to treatment start: 392 days (1.1 years); Days to treatment end: 903 days (2.5 years); Number of cycles: 2; Prescribed dose: 600; Prescribed dose units: mg/m2; Route of administration: Oral.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Sunitinib; Initial disease status: Progressive Disease; Days to treatment start: 903 days (2.5 years); Days to treatment end: 1,033 days (2.8 years); Treatment dose: 50 mg/day; Route of administration: Oral.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Sorafenib; Initial disease status: Progressive Disease; Days to treatment start: 1,033 days (2.8 years); Days to treatment end: 1,625 days (4.4 years); Prescribed dose: 400; Prescribed dose units: mg/day; Route of administration: Oral.
2. Metastasis of diagnosis 1 (Clear cell adenocarcinoma, NOS). Age at diagnosis: 58.9 years (21,517 days); Days to diagnosis: 137 days; Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: 150 days; Treatment anatomic sites: Distant Site.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Treatment given: Treatment type: Radiation Therapy, NOS.
   Recorded as not given: Surgery, NOS to Locoregional Site.

Follow-up (4 entries)
- Day 137 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Days to progression: 137 days.
- Days to follow up: 1,625 days (4.4 years); Disease response: With Tumor.
- ECOG performance status: 0.
- Karnofsky performance status: 90; ECOG performance status: 1; Timepoint: Recurrence/Progression.

Molecular and laboratory tests
- Calcium: Elevated.
- Leukocytes: Normal.
- Platelets: Normal.
- Hemoglobin: Low.
- Lactate Dehydrogenase: Normal.

Exposures
- Exposure type: Tobacco.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-CJ-6028-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 2; Intermediate dimension: 1.1; Shortest dimension: 1.
  Slide TCGA-CJ-6028-01A-01-TS1: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 65; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 20; Percent lymphocyte infiltration: 25; Percent monocyte infiltration: 3; Percent neutrophil infiltration: 1.
  Slide TCGA-CJ-6028-01A-01-BS1: Section location: Bottom; Percent tumor cells: 85; Percent tumor nuclei: 70; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 15; Percent lymphocyte infiltration: 20; Percent monocyte infiltration: 3; Percent neutrophil infiltration: 1.
- Sample TCGA-CJ-6028-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-CJ-6028-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Longest dimension: 2.7; Intermediate dimension: 0.9; Shortest dimension: 0.9.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Kidney Clear Cell Renal Carcinoma; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: With tumor; Hemoglobin level: Low; Lymph nodes examined: No.
- Drug treatment 1: Pharmaceutical therapy drug name: Oncophage; Therapy regimen: OTHER, SPECIFY IN NOTES; Therapy regimen other: Treatment of metastatic disease following cytoreductive nephrectomy.
- Drug treatment 1, Route of administrations: Route of administration: SC.
- Drug treatment 2: Therapy regimen: Progression.
- Drug treatment 3: Pharmaceutical therapy drug name: xeloda; Therapy regimen: Progression.
- Drug treatment 3, Route of administrations: Route of administration: PO.
- Radiation treatment: Radiation type other: Stereotactic radiosurgery; Therapy regimen: OTHER, SPECIFY IN NOTES; Therapy regimen other: Treatment of symptomatic brain metastases.
- Follow-up form: New tumor event surgery: No; Tumor status: With tumor; New tumor event radiation treatment: Yes; New tumor event pharmaceutical treatment: Yes; New tumor event surgery met: Yes; Performance status timing: At Recurrence/Progression Of Disease.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 1,625 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 1,625 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 137 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-CJ-6028-01A-11D-1668-01): tumor purity 0.29, ploidy 2.84, whole-genome doublings 0.
